Gene-level copy-number profile of tumor specimen HTMCP-03-06-02075-01B from CGCI case HTMCP-03-06-02075, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.4 years (19,868 days).
Specimen HTMCP-03-06-02075-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ecef8356-d606-4489-9d67-ee8c2e33cf0d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02075-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/c6f362d2-aaf0-46f9-8976-bdd80520c985

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 4,130; copy number 2: 36,715; copy number 3: 10,543; copy number 4: 5,072; copy number 5: 1,500; copy number 6: 217; copy number 7: 30; copy number 8: 79; copy number 9: 1; copy number 10: 5; copy number 16: 9.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:243,005,845–243,101,744, 6 genes: AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:41,340,823–43,045,120, 46 genes: CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr10:80,233,664–80,254,121, 3 genes: AL513174.1, EIF5AP4, AL359195.2.
- chr11:112,602,354–112,602,452, 1 gene (within-gene range 0–2): AP003063.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,841 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,487,364–151,729,805, 73 genes, copy number 6 (broad region; genes not listed).
- chr1:151,982,915–154,297,748, 136 genes, copy number 6 (broad region; genes not listed).
- chr2:13,537,673–28,450,184, 263 genes, copy number 5 (broad region; genes not listed).
- chr2:31,290,762–88,631,821, 964 genes, copy number 5 (broad region; genes not listed).
- chr2:89,252,211–96,740,064, 162 genes, copy number 5–10 (broad region; genes not listed).
- chr5:163,855,140–163,856,642, 1 gene, copy number 6: AC008432.1.
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.
- chr12:48,627,879–49,060,794, 31 genes, copy number 5: OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B, CCNT1, TEX49, AC117498.1, ADCY6, MIR4701, ADCY6-DT, AC117498.2, Y_RNA, CACNB3, DDX23, RND1, RNU6-600P, AC073610.1, AC073610.2, CCDC65, FKBP11, ARF3, WNT10B, RNU6-940P, WNT1, DDN, AC011603.3, DDN-AS1, PRKAG1, KMT2D.
- chr14:18,333,726–19,003,752, 30 genes, copy number 5–6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P.
- chr14:19,920,582–19,936,757, 2 genes, copy number 6: OR4K5, OR4K1.
- chr14:22,147,995–22,190,713, 7 genes, copy number 16: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:22,202,583–22,208,129, 2 genes, copy number 16: TRAV26-2, TRAV34.
- chr16:31,975,803–32,003,728, 1 gene, copy number 6: AC142381.3.
- chr16:32,439,069–32,441,159, 1 gene, copy number 7: PABPC1P13.
- chr19:17,226,213–17,521,288, 29 genes, copy number 7 (within-gene range 4–7): OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS.
- chr19:27,638,483–28,429,490, 19 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1.
- chr19:41,169,861–41,930,150, 51 genes, copy number 5: RPL36P16, RN7SL718P, CYP2S1, AXL, AC011510.1, HNRNPUL1, RN7SL34P, TGFB1, AC011462.5, CCDC97, AC011462.1, TMEM91, B9D2, AC011462.4, EXOSC5, BCKDHA, AC011462.3, AC011462.2, B3GNT8, DMAC2, Metazoa_SRP, ERICH4, PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10, CEACAMP3, DNAJC19P2, CEACAM4, DNAJC19P3, AC243960.5, AC243960.4, CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A, ARHGEF1, ERFL.
- chr19:57,958,437–58,605,223, 68 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,130. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
